Somatic mutation profile of tumor specimen C3N-00577-01 (aliquot CPT0069150009) from CPTAC case C3N-00577, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.7 years (26,555 days).
Specimen C3N-00577-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 401ace2d-0153-42be-9894-ee515b9ad047.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00577-71 (Blood Derived Normal), aliquot CPT0069270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c5d4c01-84f4-4c7f-aca4-6169574d7dbd

The open-access MAF lists 84 somatic variants for this specimen: 49 protein-altering or splice-affecting, 27 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 27, Intron 5, Splice Site 4, Frame Shift Del 4, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.14020A>G p.R4674G | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs80338904, CM071135; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AFF4 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208947343; called by muse, mutect2
- AQP9 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54967546; called by muse, mutect2, varscan2
- C10orf90 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs774093912; called by muse, mutect2, varscan2
- CNOT4 | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as rs759685984, CS1212371, COSV59650961; called by muse, mutect2, varscan2
- DPH5 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV59859843, COSV59860468; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- GABRB1 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs748097369, COSV54984293; called by muse, mutect2, varscan2
- GDF10 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs782581244; called by muse, mutect2, varscan2
- MYO3B | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556789877; called by muse, mutect2, varscan2
- RABL6 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs372102835; called by muse, mutect2, varscan2
- AJM1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAPN6 | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPRIN2 | c.1102_1104+20del p.X368_splice | Splice Site (DEL) | VAF 18/174 reads (10%) | called by mutect2, pindel
- CCDC166 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CDIP1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 67/700 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2
- COL22A1 | c.443del p.L148Rfs*81 | Frame Shift Del (DEL) | VAF 47/211 reads (22%) | called by mutect2, pindel, varscan2
- CPA5 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRHR2 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CXCL3 | c.308+2dup | Splice Region (INS) | VAF 29/276 reads (11%) | called by mutect2, pindel, varscan2
- DDR1 | c.2317_2320del p.V774Gfs*13 (on ENST00000324771; = p.V737Gfs*13 on NM_001954.4) | Frame Shift Del (DEL) | VAF 37/428 reads (9%) | called by mutect2, pindel
- DRD4 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 160/724 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- EPRS1 | c.1130_1131dup p.D378Mfs*7 | Frame Shift Ins (INS) | VAF 13/136 reads (10%) | called by mutect2, pindel
- FAM131C | c.563-2A>T p.X188_splice | Splice Site (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- GOLGA8J | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPD1 | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYST | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 40/505 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- MLLT10 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCOA5 | c.443dup p.Y148* | Nonsense Mutation (INS) | VAF 47/303 reads (16%) | called by mutect2, pindel, varscan2
- NOD1 | c.2369+3_2369+6del | Splice Region (DEL) | VAF 11/84 reads (13%) | called by pindel, varscan2
- OTOP2 | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PBRM1 | c.4680+2T>C p.X1560_splice (on ENST00000296302 / NM_001366071.2; = p.X1453_splice on NM_018313.5) | Splice Site (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- RABGGTA | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RDH13 | c.386G>T p.R129L (on ENST00000415061 / NM_001145971.2; = p.R58L on NM_138412.4) | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RELN | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- SHOX | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 103/751 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC12A3 | c.2668T>A p.F890I (on ENST00000563236 / NM_001126108.2; = p.F899I on NM_000339.3) | Missense Mutation (SNP) | VAF 24/741 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2
- SLC22A7 | c.943A>G p.S315G (on ENST00000372585 / NM_153320.2; = p.S313G on NM_006672.3) | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SNAP91 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- TBX5 | c.212del p.G71Afs*4 | Frame Shift Del (DEL) | VAF 125/751 reads (17%) | called by mutect2, pindel, varscan2
- THRA | c.1112A>T p.E371V | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIAM1 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TLE3 | c.88_101delinsT p.K30Cfs*29 | Frame Shift Del (DEL) | VAF 47/213 reads (22%) | called by pindel, varscan2*
- TLK1 | c.2101C>G p.P701A | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TLN1 | c.4118T>C p.V1373A | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TRIM26 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 70/540 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZFR | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 83/509 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF430 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF470 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ANKRD39 | c.264T>G p.A88= | Silent (SNP) | VAF 171/564 reads (30%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.1482C>T p.I494= | Silent (SNP) | VAF 33/619 reads (5%) | called by muse, mutect2
- BAZ2B | c.3918C>T p.D1306= | Silent (SNP) | VAF 17/412 reads (4%) | called by muse, mutect2
- CLUH | c.2169A>G p.S723= (on ENST00000435359; = p.S762= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/231 reads (13%) | called by muse, mutect2, varscan2
- CUX1 | c.57A>G p.V19= (on ENST00000292535 / NM_181552.4; = p.V30= on NM_001913.5) | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as rs1278377019; called by muse, mutect2, varscan2
- EP300 | c.3885T>C p.S1295= | Silent (SNP) | VAF 52/411 reads (13%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.57C>T p.P19= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- KMT2E | c.4833C>T p.P1611= | Silent (SNP) | VAF 67/413 reads (16%) | catalogued as rs1243172763; called by muse, mutect2, varscan2
- KRTAP4-9 | c.585C>G p.V195= | Silent (SNP) | VAF 31/344 reads (9%) | called by muse, mutect2
- LRAT | c.615T>C p.S205= | Silent (SNP) | VAF 45/307 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.11331C>G p.P3777= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV67479511; called by muse, mutect2
- OIT3 | c.312T>C p.A104= | Silent (SNP) | VAF 43/330 reads (13%) | called by muse, mutect2, varscan2
- OR9K2 | c.463C>T p.L155= (on ENST00000305377; = p.L133= on NM_001005243.1) | Silent (SNP) | VAF 46/300 reads (15%) | called by muse, mutect2, varscan2
- RGS20 | c.174G>A p.P58= | Silent (SNP) | VAF 48/264 reads (18%) | catalogued as COSV52020210; called by muse, mutect2, varscan2
- SETD1A | c.723C>A p.T241= | Silent (SNP) | VAF 76/620 reads (12%) | called by muse, mutect2, varscan2
- SIGLECL1 | c.180C>T p.T60= | Silent (SNP) | VAF 88/454 reads (19%) | called by muse, mutect2, varscan2
- SIN3A | c.300G>A p.Q100= | Silent (SNP) | VAF 36/442 reads (8%) | catalogued as COSV64582507; called by muse, mutect2
- SLC6A12 | c.780T>C p.L260= | Silent (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- TERT | c.3267C>T p.Y1089= | Silent (SNP) | VAF 50/706 reads (7%) | catalogued as rs759883263, COSV99716060; ClinVar: likely benign; called by muse, mutect2
- TIMM44 | c.438G>A p.K146= | Silent (SNP) | VAF 148/728 reads (20%) | catalogued as COSV54494255; called by muse, mutect2, varscan2
- TNFRSF25 | c.882G>A p.P294= | Silent (SNP) | VAF 22/296 reads (7%) | catalogued as rs758622492, COSV61068174; called by muse, mutect2
- TTC34 | c.2356C>T p.L786= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- TTC6 | c.820C>T p.L274= (on ENST00000267368; = p.L1640= on NM_001310135.3) | Silent (SNP) | VAF 35/291 reads (12%) | called by muse, mutect2, varscan2
- TTLL10 | c.1323A>G p.E441= (on ENST00000379289 / NM_001130045.2; = p.E368= on NM_153254.3) | Silent (SNP) | VAF 15/339 reads (4%) | catalogued as COSV64959720; called by muse, mutect2
- USP34 | c.7800C>A p.A2600= | Silent (SNP) | VAF 56/148 reads (38%) | called by muse, mutect2, varscan2
- WDR81 | c.1098G>C p.L366= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- ZNF721 | c.2469A>G p.K823= (on ENST00000338977; = p.K835= on NM_133474.4) | Silent (SNP) | VAF 37/316 reads (12%) | called by muse, mutect2, varscan2
- COPZ2 | c.112-258C>T | Intron (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
- GLRX | chr5:95823891 C>A | 5'Flank (SNP) | VAF 66/406 reads (16%) | catalogued as rs751794723; called by muse, mutect2, varscan2
- ILF3 | c.2059+856C>T | Intron (SNP) | VAF 22/122 reads (18%) | catalogued as rs766111474; called by muse, mutect2, varscan2
- LINC00602 | n.1069G>C | RNA (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- MADCAM1 | c.667+1225C>T | Intron (SNP) | VAF 24/269 reads (9%) | called by muse, mutect2
- PELP1 | c.1068+53C>T | Intron (SNP) | VAF 130/677 reads (19%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2469+17G>C | Intron (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- RPL38 | c.*15T>C | 3'UTR (SNP) | VAF 46/252 reads (18%) | catalogued as rs775963020; called by muse, mutect2, varscan2
